Somatic mutation profile of tumor specimen TCGA-WD-A7RX-01A (aliquot TCGA-WD-A7RX-01A-12D-A417-09) from TCGA case TCGA-WD-A7RX, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 71.2 years (26,006 days).
Specimen TCGA-WD-A7RX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb7c5d7d-a9a7-4db7-9ac5-43d3264c2de4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WD-A7RX-10A (Blood Derived Normal), aliquot TCGA-WD-A7RX-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cb81ed4-48fc-4f5f-9fb4-00712ad7bd5e

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 22, Silent 8, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FHOD3 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as rs368210942; called by muse, mutect2, varscan2
- GCN1 | c.5351A>G p.K1784R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs989428938; called by muse, mutect2, varscan2
- GLRA2 | c.991G>C p.A331P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54344287; called by muse, mutect2, varscan2
- MTG2 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs764457364; called by muse, mutect2, varscan2
- PMFBP1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV52822441; called by muse, mutect2, varscan2
- PRSS12 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs1021121858; called by muse, mutect2, varscan2
- ADGRL1 | c.3095G>A p.S1032N (on ENST00000340736 / NM_001008701.3; = p.S1027N on NM_014921.5) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ARID1A | c.4673_4680del p.S1558Cfs*11 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- DAZL | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 16/363 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2
- DNAH8 | c.6773G>A p.R2258K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GTPBP4 | c.1019T>G p.L340W | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- HDC | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KIRREL2 | c.1324G>T p.G442W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KPNA3 | c.1519A>G p.N507D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PKHD1L1 | c.7435C>T p.H2479Y | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLXNB3 | c.4088G>A p.C1363Y | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2
- SIT1 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A11 | c.381C>A p.H127Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SNCAIP | c.138C>A p.S46R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- STK40 | c.593T>G p.L198R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIGIT | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNIK | c.222G>T p.K74N | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZBTB4 | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- ZKSCAN4 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- AGTR2 | c.624A>T p.S208= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- C16orf71 | c.1237C>T p.L413= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- KLHL25 | c.87G>A p.P29= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs200944201; called by muse, mutect2, varscan2
- NID2 | c.1006T>C p.L336= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- NIPAL1 | c.945A>T p.T315= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- PSIP1 | c.1210C>A p.R404= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV66253598, COSV66255063; called by muse, mutect2, varscan2
- RALGAPA1 | c.1953G>A p.S651= | Silent (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- SOX3 | c.507C>T p.I169= | Silent (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
